TCGA case TCGA-XF-AAN8 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aa14e232-c6c6-4075-9d15-e1857373d233

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Dead; Days to death: 118 days.

Diagnoses (4)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.4; Tissue or organ of origin: Posterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 74.8 years (27,309 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 0; Lymph nodes tested: 54; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Breast, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 40.4 years (14,760 days); Days to diagnosis: -12,549 days (-34.4 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -12,549 days (-34.4 years); Treatment anatomic sites: Breast.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 71.3 years (26,052 days); Days to diagnosis: -1,257 days (-3.4 years); AJCC pathologic T: T1.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,257 days (-3.4 years); Treatment anatomic sites: Bladder.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Days to treatment start: -1,245 days (-3.4 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Radiation Therapy, NOS.
4. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Treatment intent type: Induction; Treatment outcome: Complete Response; Timepoint category: Prior to Procurement; Treatment outcome duration: 366.

Follow-up (2 entries)
- Karnofsky performance status: 90.
- Follow-up contact recording only the day: day 118.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 170 cm; BMI: 22.8.

Exposures
- Occupation type: Nursing and Midwifery Professionals.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 60; Age at onset: 15.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-AAN8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 1,220 mg.
  Slide TCGA-XF-AAN8-01A-01-TSA: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 75; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 3.
- Sample TCGA-XF-AAN8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-AAN8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Occupation current: retired; Occupation primary: registered nurse; Occupation primary industry: Nursing/clinical; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Bacillus Calmette-Guerin (BCG); Bcg treatment 90 days prior to resection: No; Bcg treatment complete response: Yes; Bcg treatment induction courses indicator: Yes; Bcg treatment maintenance courses indicator: Yes; Bcg complete response months: 12.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Mastectomy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: urothelial carcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Turbt.
- Other malignancy form 2, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: BCG.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 118 days; disease-specific survival: event status not recorded, 118 days; progression-free interval: no event (censored), 118 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-AAN8-01A-11D-A42D-01): tumor purity 0.58, ploidy 2, whole-genome doublings 0.
